Somatic mutation profile of tumor specimen C3N-01803-03 (aliquot CPT0384890006) from CPTAC case C3N-01803, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.5 years (23,200 days).
Specimen C3N-01803-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838f5acc-2cad-4983-b6fd-285dfaafc6dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01803-31 (Blood Derived Normal), aliquot CPT0385470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f42f53e-0a01-4adc-b13b-7c24db6fc53e

The open-access MAF lists 94 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Intron 6, Frame Shift Del 3, Frame Shift Ins 3, 5'Flank 2, Nonsense Mutation 2, RNA 2, Splice Region 1, 3'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3626G>T p.G1209V | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131692022; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAI3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54004350; called by muse, mutect2
- GYG1 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99936639; called by muse, mutect2, varscan2
- KCNA1 | c.157A>C p.K53Q | Missense Mutation (SNP) | VAF 24/630 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1240945980; called by muse, mutect2
- PCDHA11 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.563); catalogued as rs1398153775, COSV100249255; called by muse, mutect2, varscan2
- RAD50 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1341798216, COSV54751652; ClinVar: uncertain significance; called by muse, mutect2
- SERAC1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1410480111; called by muse, varscan2
- STIL | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs925156946; called by muse, mutect2
- TRPV4 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 116/578 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1167973138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.36590C>T p.T12197I (on ENST00000591111; = p.T4773I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | PolyPhen probably damaging (0.998); catalogued as rs1311776030; called by muse, mutect2, varscan2
- ZNF668 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56219903; called by muse, mutect2, varscan2
- ANKRD27 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ARHGEF11 | c.1493A>G p.K498R | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARID5B | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 41/437 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- ATP6AP1 | c.629T>A p.L210H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AZIN2 | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2
- BACE2 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2
- BEND2 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- BIRC2 | c.236dup p.D79Efs*14 | Frame Shift Ins (INS) | VAF 9/89 reads (10%) | called by mutect2, pindel
- C1orf167 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CACNA1C | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1S | c.1950C>T p.Y650= | Splice Region (SNP) | VAF 18/550 reads (3%) | called by muse, mutect2
- CAND1 | c.1361G>A p.C454Y | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCR9 | c.883A>T p.I295F (on ENST00000357632 / NM_031200.3; = p.I283F on NM_006641.4) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CERS5 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CISH | c.65T>C p.L22P (on ENST00000348721 / NM_145071.4; = p.L39P on NM_013324.6) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.188); called by muse, mutect2
- CLTCL1 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG6 | c.173dup p.A59Gfs*8 | Frame Shift Ins (INS) | VAF 29/279 reads (10%) | called by mutect2, varscan2
- DENND1C | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DMXL1 | c.4448C>A p.P1483H | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DNAH9 | c.1376del p.F459Sfs*17 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- EMX1 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FREM2 | c.7777_7779del p.Y2593del | In Frame Del (DEL) | VAF 22/208 reads (11%) | called by mutect2, pindel, varscan2
- HAUS8 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); called by muse, mutect2
- IGFN1 | c.3520T>C p.C1174R (on ENST00000295591 / NM_001367841.1; = p.C3631R on NM_001164586.2) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INPP5F | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JKAMP | c.84T>A p.C28* (on ENST00000554271 / NM_001284201.1; = p.C14* on NM_016475.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2
- KCNAB3 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.1); called by muse, mutect2
- LPIN2 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN2 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRCH3 | c.2296C>G p.P766A | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2
- MDC1 | c.6128C>A p.P2043H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- NBAS | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 35/175 reads (20%) | called by muse, mutect2, varscan2
- NEPRO | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- NFKBIE | c.457A>G p.S153G (on ENST00000275015; = p.S14G on NM_004556.3) | Missense Mutation (SNP) | VAF 108/951 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP214 | c.1871T>A p.L624H | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2
- OSBPL1A | c.1298T>G p.L433W | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCM1 | c.5168G>A p.R1723K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RNF19A | c.861del p.Y287* | Frame Shift Del (DEL) | VAF 61/270 reads (23%) | called by mutect2, pindel, varscan2
- SCUBE2 | c.1775C>G p.T592S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2
- SHANK1 | c.1822C>A p.L608M | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SIX4 | c.1191dup p.S398Ifs*12 | Frame Shift Ins (INS) | VAF 33/299 reads (11%) | called by mutect2, pindel, varscan2
- SLC22A25 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SLC40A1 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SOWAHD | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TBC1D7 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TIMM22 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- TRIM75P | c.958A>C p.K320Q | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TTN | c.99380G>A p.R33127K (on ENST00000591111; = p.R25703K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/218 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- TVP23A | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.36); called by muse, mutect2
- WDR77 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF543 | c.1314del p.F438Lfs*128 | Frame Shift Del (DEL) | VAF 44/369 reads (12%) | called by mutect2, pindel, varscan2
- ZNF608 | c.3969G>C p.K1323N | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRF2 | c.1152C>T p.I384= (on ENST00000296862 / NM_001368115.2; = p.I316= on NM_153839.7) | Silent (SNP) | VAF 15/268 reads (6%) | called by muse, mutect2
- ADH4 | c.741C>T p.L247= | Silent (SNP) | VAF 37/346 reads (11%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1401G>A p.T467= (on ENST00000321322; = p.T407= on NM_020693.4) | Silent (SNP) | VAF 50/251 reads (20%) | catalogued as rs754303629, COSV58391866; called by muse, mutect2, varscan2
- FTO | c.498T>C p.D166= | Silent (SNP) | VAF 142/673 reads (21%) | catalogued as rs1270325823; called by muse, mutect2, varscan2
- HTT | c.6216T>C p.S2072= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- IGSF9B | c.72C>T p.H24= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs766713258, COSV58068444, COSV58069286; called by muse, mutect2
- IRAG1 | c.2226T>C p.P742= | Silent (SNP) | VAF 37/350 reads (11%) | called by muse, mutect2, varscan2
- LAMTOR5 | c.255A>G p.A85= (on ENST00000602318 / NM_001382293.1; = p.A167= on NM_006402.3) | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- LRP11 | c.1458T>C p.I486= | Silent (SNP) | VAF 45/251 reads (18%) | called by muse, mutect2, varscan2
- LTBP3 | c.1806C>T p.N602= | Silent (SNP) | VAF 79/702 reads (11%) | catalogued as rs1214391090; called by muse, mutect2, varscan2
- MBD6 | c.2631C>A p.G877= | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- NDRG3 | c.120T>A p.G40= (on ENST00000349004 / NM_032013.4; = p.G28= on NM_022477.4) | Silent (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- NEPRO | c.891A>G p.V297= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- NMRAL1 | c.330C>G p.V110= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- PKHD1 | c.8922C>T p.F2974= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as COSV61896492; called by muse, mutect2, varscan2
- PNPLA5 | c.42C>T p.F14= | Silent (SNP) | VAF 59/369 reads (16%) | catalogued as COSV99336545; called by muse, mutect2, varscan2
- POLE2 | c.1188A>G p.S396= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV53562198; called by muse, mutect2, varscan2
- TSPAN15 | c.396T>A p.I132= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- ZNF668 | c.576C>A p.G192= | Silent (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503034 del AG | 5'Flank (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- DCHS2 | n.8575C>G | RNA (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- HAAO | c.484+27C>T | Intron (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- HNRNPC | c.837+28A>T | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2
- KCNIP4 | c.62-101183C>A | Intron (SNP) | VAF 16/212 reads (8%) | catalogued as rs1287394722; called by muse, mutect2
- LAD1 | chr1:201399411 C>A | 5'Flank (SNP) | VAF 62/472 reads (13%) | catalogued as COSV66212967; called by muse, mutect2, varscan2
- MKRN2 | chr3:12585086 C>A | 3'Flank (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- NSG2 | c.*172G>A | 3'UTR (SNP) | VAF 36/334 reads (11%) | called by muse, mutect2
- RNF32 | c.417+16G>C | Intron (SNP) | VAF 8/90 reads (9%) | catalogued as COSV58732036; called by muse, mutect2
- STAG3L2 | n.1337T>A | RNA (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2, varscan2
- TMEM184A | c.644+279T>C | Intron (SNP) | VAF 51/336 reads (15%) | catalogued as rs1287736847; called by muse, mutect2, varscan2
- ZNF117 | c.34+61A>G | Intron (SNP) | VAF 30/403 reads (7%) | called by muse, mutect2
